FM case AD15125 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/ba0cbef1-5057-49a2-b6f2-7ea2b3d7f8da

Female, 30.9 years: Carcinoma, NOS (ICD-O-3 8010/3) of the breast; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 52% (pathologist estimate recorded by GDC). Sample type: Metastatic.
